NCICCR case DLBCL11648 — Genomic Variation in Diffuse Large B Cell Lymphomas (NCICCR-DLBCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Lymph nodes.
https://portal.gdc.cancer.gov/cases/a613d6e6-e794-446e-8556-9643278625bb

Demographics
Sex at birth: male; Vital status: Alive.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: Tissue or organ of origin: Lymph node, NOS; Site of resection or biopsy: Lymph node, NOS; Age at diagnosis: 61.0 years (22,265 days).

Biospecimens (1 sample)
- Sample DLBCL11648-sample: Sample type: Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Lymphocytes; Preservation method: Frozen.
